TCGA case TCGA-27-2519 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ff96a7e-1b96-4530-b8a8-7f2e9e541955

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 550 days (1.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 48.5 years (17,715 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: -10 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 16; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Levetiracetam; Treatment intent type: Adjuvant; Days to treatment start: -10 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 1500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 95 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 95 days; Number of cycles: 1; Treatment dose: 6,440 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 133 days; Days to treatment end: 259 days; Number of cycles: 5; Treatment dose: 7,500 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fotemustine; Treatment intent type: Adjuvant; Days to treatment start: 302 days; Number of cycles: 3; Treatment dose: 390 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 130; Prescribed dose units: mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 49.2 years (17,971 days); Days to diagnosis: 256 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 274 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 256 (post initial treatment): Progression or recurrence: Yes; Days to progression: 256 days.
- Days to follow up: 316 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 550.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-27-2519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-27-2519-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
  Slide TCGA-27-2519-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
- Sample TCGA-27-2519-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-27-2519-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Follow-up form 2: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 550 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 550 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 256 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-27-2519-01A-01D-0784-01): tumor purity 0.7, ploidy 1.91, whole-genome doublings 0.
